Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A25X, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A25X-01A (Primary Tumor).

[page 1 of 2]
LABORATORY SERVICES

Accession #:
Name:
Patient ID:
PHN:
ALT ID:
DOB:
Telephone:
Requesting Physician:
Encounter:
Chart ID:

100-0-3
carcinoma, hepatocellular, NOS
8170/3
Site: liver C22.0
lw 4/25/11

Collection Site:

HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers:

ORIGINAL REPORT

SPECIMEN:

- A. Gallbladder
- B. Segment 5 & 6 liver

CLINICAL HISTORY:

Chronic Hep B. Portal vein embolization. Segment 5 and 6 hepatoma.

DIAGNOSIS:

- A. GALLBLADDER, CHOLECYSTECTOMY:
- CHRONIC CHOLECYSTITIS.

- B. LIVER, SEGMENTAL RESECTION:

- CHRONIC HEPATITIS CONSISTENT WITH HEPATITIS B GRADE 2, STAGE 2.
- HEPATOCELLULAR CARCINOMA, POORLY DIFFERENTIATED, RESECTION MARGIN UNINVOLVED.
- IRON OVERLOAD (3+).

Reported:

Reported by:
Signed by:

(Electronic Signature)

GROSS DESCRIPTION:

A. The specimen consists of a 7.3 x 2.7 x 2.1 cm gallbladder that has a tan-grey outer serosa that appears complete apart from the area of attachment to the liver bed. It contains a viscous dark green fluid without calculi. Around the proximal end of the gallbladder and extending down to the midportion is a cord-like portion of fibrofatty tissue without nodularity. The inner mucosa is bile stained and velvety and speckled with pinpoint yellow lesions. Cassettes submitted as follows: representative sections of gallbladder in block A.

B. The specimen consists of a 12.5 x 10.5 x 6 cm portion of liver weighing 301 g. It has previously been inked with silver nitrate and the surgical margin has been inked black. Within the liver there is a 6.5 x 5.3 x 5.1 cm irregularly circumscribed tan-yellow multiply lobulated smooth heterogeneous

FINAL

Printed:
Name:

[page 2 of 2]
LABORATORY SERVICES

Accession #:

Name:

Patient ID:

PHN:

ALT ID:

DOB:

Telephone:

Requesting Physician:

Encounter:

Chart ID:

Collection Site:

HISTOPATHOLOGY REPORT

Division Head:

Inquiry Numbers:

GROSS DESCRIPTION:

lesion. It abuts the serosa and is creating nodules on the serosal surface. It comes to within 1.3 cm of the surgical margin. As well there is a similar appearing lesion that is 1.0 cm in diameter that is 0.7 cm away from the major lesion, 0.9 cm away from the serosal surface, and 1.0 cm away from the surgical margin. The remainder of the parenchyma has an orange-brown heterogeneous slightly nodular appearance. Cassettes submitted as follows:

- B1,B2 - liver parenchyma uninvolved by tumor.
- B3 - portion of tumor abutting serosal surface.
- B4 - tumor with serosal nodule.
- B5 - section of parenchyma between nodules.
- B6 - smaller tumor with serosal and surgical margin.
- B7 - largest tumor with surgical margin.
- B8 - representative section of tumor.
- B9 - representative section of tumor with serosa.

MICROSCOPIC DESCRIPTION:

B. Sections of liver away from the tumor show a preserved lobular architecture. The portal areas are expanded due to inflammatory cell infiltration and fibrosis. Piecemeal necrosis and portal to portal fibrous strands are present. The lobular parenchyma shows spotty necrosis and sinusoidal permeation by lymphocytes. Mild macrovesicular steatosis is also present. Special stain for iron shows iron overload in hepatocytes (3+) and special stain for alpha 1 antitrypsin globules is negative.

Cc:

Procedure:

Received:

Printed:

Name:

FINAL

Source: NCI Genomic Data Commons file f1e68ed4-461f-4e4d-b806-6f16a0e83a01 (TCGA-G3-A25X.7DF1A9E2-3A8F-4A9B-B918-4133D60E4F0A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).